TCGA case TCGA-CM-6675 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fce1fd5a-54d2-4260-b187-4eb7035e96e9

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 35 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 35.4 years (12,935 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2b; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IVB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 397 days (1.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 12; Lymph nodes tested: 72; Lymphatic invasion present: No; Non nodal tumor deposits: Yes; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 184 days; Number of cycles: 12; Treatment dose: 32,600 mg; Prescribed dose: 2800; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 178 days; Number of cycles: 12; Treatment dose: 9,400 mg; Prescribed dose: 900; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin Calcium; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 184 days; Number of cycles: 12; Treatment dose: 9,400 mg; Prescribed dose: 900; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 150 days; Number of cycles: 10; Treatment dose: 1,780 mg; Prescribed dose: 190; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Pegfilgrastim; Treatment intent type: Adjuvant; Days to treatment start: 54 days; Days to treatment end: 152 days; Number of cycles: 7; Treatment dose: 42 mg; Prescribed dose: 6; Prescribed dose units: mg; Route of administration: Subcutaneous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Floxuridine + Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium; Days to treatment start: 337 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Days to treatment start: 366 days (1.0 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 36.3 years (13,272 days); Days to diagnosis: 337 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Days to follow up: 153 days; Disease response: Tumor Free.
- Day 337 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 337 days.
- Days to follow up: 397 days (1.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 2 ng/mL.
- MLH1 (IHC): Loss of Expression.
- MSH2 (IHC): Loss of Expression.
- MSH6 (IHC): Loss of Expression.
- PMS2 (IHC): Loss of Expression.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 93.9 kg; Height: 187 cm; BMI: 26.9.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CM-6675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 2; Shortest dimension: 0.4.
  Slide TCGA-CM-6675-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-CM-6675-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 8; Percent necrosis: 5; Percent stromal cells: 12.
- Sample TCGA-CM-6675-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CM-6675-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 2.0; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Not Expressed; Mismatch rep proteins loss IHC: MSH2-Not Expressed; Mismatch rep proteins loss IHC: PMS2-Not Expressed; Mismatch rep proteins loss IHC: MSH6-Not Expressed.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4, Route of administrations: Route of administration: SC.
- Drug treatment 6: Pharmaceutical therapy drug name: IRINOtecan HCl.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 397 days; disease-specific survival: no event (censored), 397 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 337 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CM-6675-01A-11D-1834-01): tumor purity 0.93, ploidy 1.84, whole-genome doublings 0.
